Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6353, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6353-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. PROSTATE

TCGA - G9 - 6353

SPECIMEN(S):

A. PROSTATE

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the patient identification and designated as "Part A, Prostate" is a 41g resected 5.0cm from right to left, 4.0cm from anterior to posterior, and 2.3cm from apex to base, with attached right and left seminal vesicles and vas deferens. The capsule is tan pink smooth and intact. The specimen is inked as follows: Anterior-Orange, Posterior-Black, Apex-Red, Base-Blue, Right-Green, Left-Yellow. After removal of the apex and base, the remaining prostate weight is 22g. The specimen is serially sectioned from apex to base to reveal firm tan fibrous parenchyma. No obvious lesions or nodules are grossly identified. The attached right and left seminal vesicles are 4.0 x 2.0 x 1.0cm and 5.0 x 2.6 x 1.0cm, respectively, are sectioned to beige tan cystic tissue with no gross evidence of tumor involvement. The attached right and left segments of vas deferens are 2.5 x 0.4cm and 3.2 x 0.5cm, respectively, are sectioned to reveal firm tan tubular structure with no gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (Levels I and III). The remainder of the specimen is submitted as follows:

A1-A2: right apex

A3: left apex

A4: Level I right anterior capsule

A5: Level I right posterior capsule

A6: Level I left anterior capsule

A7: Level I left posterior capsule

A8: Level II right anterior

A9: Level II right posterior

A10: Level II left anterior

A11: Level II left posterior

A12: Level III right anterior capsule

A13: Level III right posterior capsule

A14: Level III left anterior capsule

A15: Level III left posterior capsule

A16-A17: right base with periurethral margin

A18: left base with periurethral margin

A19: right lateral base

A20: left lateral base

A21: right base

A22: left base

A23: right seminal vesicle and vas deferens

A24: left seminal vesicle and vas deferens

DIAGNOSIS:

A. PROSTATE, PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (3+4),
PRESENT IN BILATERAL PROSTATE FROM APEX TO MID.
- CARCINOMA INVOLVING APPROXIMATELY 40% OF PROSTATIC
GLAND.
- FOCAL EXTRAPROSTATIC EXTENSION IDENTIFIED IN RIGHT MID PROSTATE..
- CARCINOMA FOCALLY EXTENDING TO SURGICAL RESECTION MARGIN OF RIGHT MID
PROSTATE.
- BILATERAL SEMINAL VESICLE, NEGATIVE FOR TUMOR.

SYNOPTIC REPORT - PROSTATE GLAND

Location: Bilateral prostate from apex to mid, peripheral zones

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 40%

[page 2 of 2]
Gleason Grade/Sum:: Grade 3 + 4 , Sum 7
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: Yes
Details: right posterior mid (section A5, level 2).
Bladder Neck Involved: No
Margins Involvement: Yes
Location: Right mid prostate (A4)
Linear Distance: Focal (1-10mm)
Frozen Performed: No
Post Hormonal Therapy Change: No
Lymph Nodes: No lymph nodes sampled
Other Pathologic Findings: BPH
Pathological Staging (pTNM): p T 3a N X M X

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Prostate Cancer.

Source: NCI Genomic Data Commons file a7724ed0-3389-46b4-8285-8b554630db35 (TCGA-G9-6353.72B2694F-8B37-402A-A75A-2A50372A789E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).